Somatic mutation profile of tumor specimen MMRF_1112_3_BM_CD138pos (aliquot MMRF_1112_3_BM_CD138pos_T1_KHS5U_L12903) from MMRF case MMRF_1112, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.5 years (21,725 days).
Specimen MMRF_1112_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59db8797-7d1f-4a5d-943e-128ac5906d2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1112_3_PB_WBC (Blood Derived Normal), aliquot MMRF_1112_3_PB_WBC_C6_KHS5U_L13762; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/629f5f26-fcf3-4537-82bf-a7dfa7e77d30

The open-access MAF lists 237 somatic variants for this specimen: 99 protein-altering or splice-affecting, 31 silent, 107 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, 3'UTR 61, Intron 32, Silent 31, Nonsense Mutation 7, 5'UTR 7, RNA 3, 3'Flank 2, 5'Flank 2, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA13 | c.6949C>G p.L2317V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV71284928; called by muse, varscan2
- ACAN | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 58/451 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV100717753, COSV100719431; called by muse, mutect2, varscan2
- ADAM12 | c.424A>T p.R142W | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100901828; called by muse, mutect2, varscan2
- APBB1 | c.1456G>C p.A486P | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs772276564; called by muse, mutect2, varscan2
- AQR | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 91/443 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs777010010, COSV50035720; called by muse, mutect2, varscan2
- ASPM | c.6241A>G p.K2081E | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs587783256; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC42BPB | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774720497; called by muse, mutect2
- CSMD1 | c.3873G>T p.L1291F (on ENST00000520002; = p.L1290F on NM_033225.6) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59347226; called by muse, mutect2, varscan2
- DNAH7 | c.10915G>A p.E3639K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762932607; called by muse, mutect2, varscan2
- DTNBP1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as rs376670611; called by muse, mutect2, varscan2
- GASK1B | c.1488A>G p.I496M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs781523565; called by muse, mutect2, varscan2
- GLIS2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs377037409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPCPD1 | c.1420T>C p.S474P | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs569976354; called by muse, mutect2, varscan2
- HDAC10 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757170869; called by muse, mutect2, varscan2
- HTR1F | c.698G>C p.S233T | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs759114776, COSV100137884; called by muse, mutect2
- IGHD3-9 | c.2T>A p.V1E | Missense Mutation (SNP) | VAF 14/17 reads (82%) | catalogued as rs781816980; called by muse, mutect2, varscan2
- IGHV4-34 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 45/129 reads (35%) | catalogued as rs780424322; called by muse, mutect2, varscan2
- IGLL5 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.133); catalogued as rs774342744, COSV73251209; called by muse, varscan2
- IGLL5 | c.125T>A p.M42K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs140298238; called by muse, varscan2
- IGLV3-1 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs537896918; called by muse, varscan2
- ITGA2B | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52232695; called by muse, mutect2, varscan2
- ITIH2 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs748510779; called by muse, mutect2, varscan2
- KAZN | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs557052356; called by muse, mutect2, varscan2
- KLHL3 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59055182; called by muse, mutect2, varscan2
- LRRC27 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs780399858; called by muse, mutect2, varscan2
- MDGA2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264444599; called by muse, mutect2, varscan2
- MUL1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs774965777; called by muse, mutect2, varscan2
- NALCN | c.5098G>A p.V1700M | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.143); catalogued as rs761894809, COSV51938862; called by muse, mutect2, varscan2
- NCAM2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1215881151; called by muse, mutect2
- NEURL1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.057); catalogued as rs1198902087; called by muse, mutect2, varscan2
- NWD2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV100519940; called by muse, mutect2, varscan2
- PCDHA2 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV100974138, COSV65371086; called by muse, mutect2, varscan2
- PTPRU | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs574283151, COSV100111552; called by muse, mutect2, varscan2
- RAB11A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs759435629, COSV56042311; called by muse, mutect2
- SIRT6 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs375232383; called by muse, mutect2, varscan2
- SRCAP | c.3452C>T p.T1151M | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs767622045; called by muse, mutect2, varscan2
- STYXL2 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs772856160, COSV99608585; called by muse, mutect2, varscan2
- TRIL | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV59867319; called by muse, mutect2, varscan2
- TSKS | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs755133449; called by muse, mutect2, varscan2
- ZNF467 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as rs1454283279; called by muse, mutect2, varscan2
- ABL2 | c.2758G>A p.A920T (on ENST00000502732 / NM_007314.4; = p.A905T on NM_005158.5) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB2 | c.4040C>T p.S1347F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.053); called by muse, mutect2
- ADI1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AP4E1 | c.574T>G p.L192V | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- B4GALNT3 | c.687C>G p.S229R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BCAR1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.119); called by muse, mutect2
- CD79A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 80/277 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CDT1 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN6 | c.1056A>C p.L352F | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CRLF2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CUTC | c.509T>A p.L170* | Nonsense Mutation (SNP) | VAF 33/281 reads (12%) | called by muse, mutect2, varscan2
- CYP4A11 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- DDX28 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DHX8 | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM151B | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2
- FBLL1 | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.021); called by muse, mutect2
- GIMD1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGHV4-34 | c.178T>A p.W60R | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- KNTC1 | c.6334A>C p.M2112L | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- KRT75 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LCP1 | c.1185A>T p.R395S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LMF2 | c.2083C>G p.P695A | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- MANEAL | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MFN2 | c.1834_1839del p.S612_R613del | In Frame Del (DEL) | VAF 12/117 reads (10%) | called by mutect2, pindel, varscan2
- MMP2 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MOGAT3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- MS4A3 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); called by mutect2, varscan2
- MSANTD2 | c.972G>A p.W324* (on ENST00000374979 / NM_001308027.2; = p.W272* on NM_024631.4) | Nonsense Mutation (SNP) | VAF 20/205 reads (10%) | called by muse, mutect2
- MYO5C | c.4148A>C p.K1383T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NCOR2 | c.2504C>A p.P835H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2
- NLRP11 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NR5A1 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5B12 | c.330T>G p.S110R | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PLCB2 | c.1140dup p.D381Rfs*9 | Frame Shift Ins (INS) | VAF 34/256 reads (13%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM2 | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PROSER2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTPN4 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM6 | c.2092G>A p.G698R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF34 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEPTIN8 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEZ6 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- SH3PXD2A | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- SHANK3 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SIGIRR | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC12A1 | c.2510A>G p.E837G | Missense Mutation (SNP) | VAF 150/395 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TCP10L2 | c.498+2T>C p.X166_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | called by mutect2, varscan2
- TM9SF3 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM41B | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); called by muse, mutect2
- TOPAZ1 | c.4815G>T p.Q1605H | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAPPC8 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- TRIM38 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2
- TRIM66 | c.2727G>A p.K909= | Splice Region (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TRIT1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- USP45 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZBED4 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ZHX3 | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF140 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK5 | c.909G>A p.V303= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- BCL2L1 | c.669G>C p.V223= (on ENST00000307677 / NM_001317919.2; = p.V160= on NM_001191.4) | Silent (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- BCL7A | c.21A>G p.R7= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- BRCA2 | c.6648C>T p.S2216= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- CAD | c.192A>C p.P64= | Silent (SNP) | VAF 39/287 reads (14%) | catalogued as rs1413755799; called by muse, mutect2, varscan2
- CASS4 | c.744G>T p.V248= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- CDCP1 | c.417G>C p.L139= | Silent (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- CDT1 | c.132C>T p.T44= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- HLA-DMB | c.495T>A p.T165= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- IGFBP2 | c.495C>T p.S165= | Silent (SNP) | VAF 68/222 reads (31%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.204G>A p.G68= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as rs587731145; called by muse, varscan2
- IGHV4-34 | c.177C>T p.Y59= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as rs11546810; called by muse, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs56055217, COSV73249379; called by muse, varscan2
- INCENP | c.1977G>A p.R659= (on ENST00000394818 / NM_001040694.2; = p.R655= on NM_020238.3) | Silent (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.41274G>A p.V13758= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs1214490718; called by muse, mutect2, varscan2
- MUC2 | c.2952C>T p.S984= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs374214648; called by muse, mutect2, varscan2
- PER1 | c.2853G>A p.S951= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs141195768; called by muse, mutect2, varscan2
- POLD1 | c.600G>T p.G200= | Silent (SNP) | VAF 32/339 reads (9%) | called by muse, mutect2
- R3HDM1 | c.1728G>A p.Q576= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.675C>T p.C225= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- ROCK1 | c.1768C>A p.R590= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as rs188053260; called by muse, mutect2, varscan2
- RPS6KC1 | c.1773T>C p.S591= | Silent (SNP) | VAF 86/224 reads (38%) | called by muse, mutect2, varscan2
- SARDH | c.315C>T p.T105= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs1438248593; called by muse, mutect2
- SEC31B | c.1518A>T p.L506= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs781227372; called by muse, mutect2, varscan2
- SGMS2 | c.174C>T p.D58= | Silent (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
- SLC22A14 | c.867C>T p.I289= | Silent (SNP) | VAF 56/213 reads (26%) | catalogued as rs769090429, COSV56196111; called by muse, mutect2
- SOGA3 | c.2473C>T p.L825= | Silent (SNP) | VAF 85/245 reads (35%) | called by muse, mutect2, varscan2
- TENT5B | c.624G>A p.V208= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- TLK2 | c.1317G>A p.R439= (on ENST00000326270 / NM_001284333.2; = p.R417= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- TRBV7-1 | c.195A>G p.P65= | Silent (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1998G>A p.E666= (on ENST00000252463; = p.E721= on NM_032805.3) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1241559501; called by muse, mutect2, varscan2
- AANAT | chr17:76466197 C>A | 5'Flank (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- ACIN1 | c.2298-1880_2298-1874del | Intron (DEL) | VAF 50/177 reads (28%) | called by mutect2, pindel, varscan2
- ACTN2 | c.*1135A>G | 3'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as rs1028208180; called by mutect2, varscan2
- ADAMTSL1 | c.1574+116A>G | Intron (SNP) | VAF 44/199 reads (22%) | called by muse, mutect2, varscan2
- ADGRD1 | c.*1049T>G | 3'UTR (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- ADRA1A | chr8:26865631 C>T | 5'Flank (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- AJAP1 | c.*5452C>T | 3'UTR (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- AMER3 | c.*480T>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs947035503; called by muse, mutect2
- ANKRD13C | c.*321A>T | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- ANXA2R | c.-621T>C | 5'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+1231A>G | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ATP5MC3 | c.*682A>G | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*5462A>T | 3'UTR (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- ATP8B2 | c.*602G>A | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- BASP1 | c.*638C>G | 3'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- C19orf25 | c.131-80G>A | Intron (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- CACNA1D | c.3870+522G>C | Intron (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- CACNA1D | c.3870+524G>A | Intron (SNP) | VAF 25/268 reads (9%) | catalogued as rs186912238; called by muse, mutect2
- CD74 | c.*461C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- CDKN2AIPNL | c.240-653C>G | Intron (SNP) | VAF 16/214 reads (7%) | catalogued as rs1434147657; called by muse, mutect2
- CDKN2B | c.*1163T>A | 3'UTR (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- CEP295 | c.5850+243G>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- CEP78 | c.*8657G>A | 3'UTR (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- CERS3 | c.*917G>A | 3'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- CYP27C1 | c.*2408G>A | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- DAAM1 | c.183+37G>A | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- DDX52 | c.*80G>A | 3'UTR (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- DPYSL3 | c.*2653G>T | 3'UTR (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- DTX4 | c.*3437T>A | 3'UTR (SNP) | VAF 27/244 reads (11%) | called by muse, mutect2, varscan2
- ELFN2 | c.*4601G>A | 3'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- EPAS1 | c.*882G>T | 3'UTR (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- GALNT10 | c.1056+1222T>G | Intron (SNP) | VAF 55/95 reads (58%) | called by muse, mutect2, varscan2
- GCKR | c.-50T>G | 5'UTR (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- GNA12 | c.*920T>C | 3'UTR (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- GRIK2 | c.1748+514T>G | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- HCN1 | c.*1022A>G | 3'UTR (SNP) | VAF 32/121 reads (26%) | catalogued as rs1005282055, COSV100300036; called by muse, varscan2
- HS3ST3B1 | c.*952T>G | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- IBA57 | c.*1396G>T | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.*4221C>A | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- KCNJ15 | c.*810G>A | 3'UTR (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- KREMEN1 | chr22:29143411 G>C | 3'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- KRTAP4-9 | c.*289A>T | 3'UTR (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- KRTDAP | c.*83A>G | 3'UTR (SNP) | VAF 37/348 reads (11%) | catalogued as rs1254754565; called by muse, mutect2, varscan2
- LINC01591 | n.514G>A | RNA (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3350+2015C>T | Intron (SNP) | VAF 63/164 reads (38%) | called by muse, mutect2, varscan2
- LRP1 | c.2797+65G>A | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- LSG1 | c.*590A>C | 3'UTR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- LTB | c.208+13T>C | Intron (SNP) | VAF 72/370 reads (19%) | called by muse, mutect2
- LTB | c.208+11A>C | Intron (SNP) | VAF 73/378 reads (19%) | called by muse, mutect2
- LUC7L | c.62-865C>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- LZTFL1 | c.*662A>G | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- MAP2K3 | c.*710G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MAP4 | c.2000-14390A>T | Intron (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- MAP4 | c.292+3486G>A | Intron (SNP) | VAF 3/15 reads (20%) | catalogued as rs1363242559; called by muse, mutect2
- MID1 | c.*2170A>G | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- MTARC1 | c.*580G>A | 3'UTR (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- NDUFA6 | c.*237A>G | 3'UTR (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- NFE2L3 | c.*65_*84del | 3'UTR (DEL) | VAF 32/149 reads (21%) | called by mutect2, pindel, varscan2
- NFIA | c.*7353del | 3'UTR (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- NUDT16 | c.*4107A>T | 3'UTR (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- OTULIN | c.*5871G>C | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- PARVA | c.798+80G>A | Intron (SNP) | VAF 81/316 reads (26%) | catalogued as rs763580065; called by muse, mutect2, varscan2
- PBX1 | c.*1909G>T | 3'UTR (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- PHC3 | c.*310_*318del | 3'UTR (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- PHF2 | c.*759G>A | 3'UTR (SNP) | VAF 23/211 reads (11%) | catalogued as rs1050862010; called by muse, mutect2, varscan2
- PLCXD3 | c.-86C>A | 5'UTR (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.*143G>C | 3'UTR (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- POU6F2 | chr7:39466108 C>T | 3'Flank (SNP) | VAF 6/41 reads (15%) | catalogued as rs1413071628; called by muse, mutect2, varscan2
- PRKG1 | c.*4094C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- PSCA | c.134-121C>A | Intron (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- PTH | c.*233A>G | 3'UTR (SNP) | VAF 32/57 reads (56%) | catalogued as rs558107542; called by muse, mutect2, varscan2
- QPCT | c.723+884G>A | Intron (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- RASSF10 | c.-14G>A | 5'UTR (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- RNASE6 | c.*178C>G | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- RSPO4 | c.*1686G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- RUFY4 | c.-29G>A | 5'UTR (SNP) | VAF 96/262 reads (37%) | catalogued as rs540646444; called by muse, mutect2, varscan2
- S1PR3 | c.-147-4088C>T | Intron (SNP) | VAF 17/117 reads (15%) | catalogued as rs184492109; called by muse, mutect2, varscan2
- SEMA5A | c.*4872T>C | 3'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.*1914T>C | 3'UTR (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- SERPINB6 | c.48-935G>T | Intron (SNP) | VAF 35/224 reads (16%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.*162_*165del | 3'UTR (DEL) | VAF 46/127 reads (36%) | catalogued as rs1337008696; called by mutect2, pindel, varscan2
- SLC25A17 | c.55-533G>C | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6632C>T | Intron (SNP) | VAF 28/58 reads (48%) | catalogued as rs984058521; called by muse, mutect2, varscan2
- SLC6A3 | c.*453A>T | 3'UTR (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- SNX29P1 | n.654C>G | RNA (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- SORL1 | c.*2152T>A | 3'UTR (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- SPRED3 | c.424-265G>A | Intron (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- SPRY4 | c.*1754T>G | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ST8SIA1 | c.236+8100C>T | Intron (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- TAF8 | c.*79G>A | 3'UTR (SNP) | VAF 23/291 reads (8%) | catalogued as rs1313210003; called by muse, mutect2
- TCF7 | c.1026+67C>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- TCP10L3 | n.2719+1831del | Intron (DEL) | VAF 47/292 reads (16%) | called by mutect2, varscan2
- TCP10L3 | n.631T>C | RNA (SNP) | VAF 18/144 reads (13%) | called by mutect2, varscan2
- THY1 | c.*234C>G | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- TIMP3 | c.*2085A>C | 3'UTR (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- TMEM138 | c.376+193G>A | Intron (SNP) | VAF 15/131 reads (11%) | called by muse, varscan2
- TMEM170B | c.*7534A>C | 3'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- TPH1 | c.*129T>A | 3'UTR (SNP) | VAF 19/241 reads (8%) | called by muse, mutect2
- TRAF3 | c.*1497G>A | 3'UTR (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- TUBB | c.58-813T>C | Intron (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- UBR5 | c.*1001A>C | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- UTY | c.-93G>C | 5'UTR (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- VNN1 | c.*707G>A | 3'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- WDR33 | c.725-10857G>A | Intron (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- ZNF43 | c.*197A>G | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- ZNF576 | c.*328C>G | 3'UTR (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2, varscan2
- ZNF688 | c.-919A>G | 5'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
